Somatic mutation profile of tumor specimen TARGET-10-PAPEFH-03A (aliquot TARGET-10-PAPEFH-03A-01D) from TARGET case TARGET-10-PAPEFH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,543 days).
Specimen TARGET-10-PAPEFH-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4f8a293-74ff-4e6c-948c-cb5ac7b0e6c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPEFH-14A (Bone Marrow Normal), aliquot TARGET-10-PAPEFH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6542a752-c332-456b-b252-74e40f1f51a6

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Frame Shift Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2624C>A p.T875N | Missense Mutation (SNP) | VAF 276/378 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1057520016, COSV67598981; ClinVar: likely pathogenic; called by mutect2, varscan2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 52/74 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, varscan2
- C2CD3 | c.2314A>G p.S772G | Missense Mutation (SNP) | VAF 31/818 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV58091848; called by muse, mutect2
- CSF1R | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 332/908 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs200702302; called by muse, mutect2, varscan2
- DGAT2L6 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 135/347 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60717471; called by muse, mutect2, varscan2
- DIAPH2 | c.149C>G p.T50S | Missense Mutation (SNP) | VAF 26/746 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.281); catalogued as COSV61265156; called by muse, mutect2
- DNAJC5G | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs539866520, COSV56079741, COSV56080959; called by muse, mutect2, varscan2
- KCNC3 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65387128; called by muse, mutect2
- KMT2D | c.857_858insGGAC p.K287Dfs*2 | Frame Shift Ins (INS) | VAF 82/275 reads (30%) | catalogued as COSV56464530, COSV99982352; called by mutect2, pindel, varscan2
- MUC5B | c.9344C>T p.T3115M | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs563537111, COSV71591530; called by mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 233/525 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NT5C1B | c.197_201del p.L66Rfs*3 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as COSV58395239; called by mutect2, pindel, varscan2
- POLR2A | c.4063G>A p.V1355I | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as rs746137888; called by muse, mutect2, varscan2
- QRICH2 | c.2171G>T p.G724V | Missense Mutation (SNP) | VAF 99/119 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV53152302; called by muse, mutect2, varscan2
- SPRY3 | c.390G>C p.K130N | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as COSV57142461; called by muse, mutect2, varscan2
- UBR4 | c.12349T>C p.S4117P | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV64386371; called by muse, mutect2, varscan2
- GJB3 | c.768C>A p.G256= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV64904496; called by muse, mutect2, varscan2
- KDM3B | c.852C>G p.G284= | Silent (SNP) | VAF 120/260 reads (46%) | catalogued as COSV58689704; called by muse, mutect2, varscan2
- LUC7L2 | c.726A>G p.E242= | Silent (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- MFSD2A | c.450C>T p.P150= (on ENST00000372809 / NM_001136493.3; = p.P137= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 162/385 reads (42%) | catalogued as rs749348699, COSV65685354; called by muse, mutect2, varscan2
- OTUD5 | c.1284G>T p.R428= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV50240801; called by muse, varscan2
- PTPN13 | c.795T>G p.R265= | Silent (SNP) | VAF 72/171 reads (42%) | catalogued as rs746374562, COSV57405158; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-15199A>T | Intron (SNP) | VAF 113/289 reads (39%) | catalogued as COSV67442502; called by muse, mutect2, varscan2
